Surgical pathology report (de-identified scan), TCGA case TCGA-21-5782, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-5782-01A (Primary Tumor).

[REDACTED]

Clinical History/Diagnosis: Cancer left lung.

Source of Specimen(s):

A: Lung, wedge biopsy left lower lobe

B: Lymph Node, level 9L

[REDACTED] TCGA-21-5782

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled #1 "left lower lobe of lung wedge"

Gross Description: Received fresh is an 84.8 gm, 13.5 x 5.0 x 3.0 cm wedge of lung. It is covered by a red-purple focally anthracotic stained pleura having multiple staples along one margin. The pleural margins are inked in black, the staples are removed and the newly created margin is inked in blue. The specimen is serially sectioned to reveal red-purple glistening cut surfaces. There is a 3.5 x 3.0 x 3.0 cm firm mass having tan focally hyperemic slightly nodular cut surfaces. Representative sections are submitted in six blocks.

Designation of Sections: 1A-1B tumor with inked stapled (blue) margin, 1C-1D tumor with inked pleural margin, 1E additional representative section tumor, 1F random sections lung.

Summary of Sections: multiple

Source of Tissue: 2. Labeled #2 "level 9L lymph nodes"

Gross Description: Received fresh is a 1.0 cm in greatest dimension gray-black anthracotic stained lymph node which is bisected and entirely submitted in one block.

Designation of Sections: block 2

Summary of Sections: undesignated 2

Final Diagnosis:

1. Lung, left lower lobe (wedge biopsy):
- Invasive, poorly differentiated, squamous cell carcinoma (3.5 cm).
- Negative pleura and inked resection margin.
- Pulmonary parenchyma showing emphysematous changes.

2. Level 9L lymph node (excision):
- One lymph node negative for metastatic carcinoma (0/1).
- [REDACTED]

Source: NCI Genomic Data Commons file 08f02baa-fe0e-4f6f-b15d-36d20a61fe26 (TCGA-21-5782.644E67C4-61CD-40F8-B2CB-287B8A868EB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).